MMRF case MMRF_2226 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ce950fb2-be89-4061-a3af-a104d8021530

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.4 years (24,616 days); ISS stage: II; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -4 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL.
- Hemoglobin 7.38 mmol/L.
- Total Protein 10.2 g/dL.
- Immunoglobulin M 0.19 g/L.
- Leukocytes 13.9 ×10⁹/L.
- Platelets 205 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 22.5 mg/dL.
- Calcium 2.58 mmol/L.
- Immunoglobulin G 34.1 g/L.
- Albumin 31 g/L.
- Lactate Dehydrogenase 3.77 µkat/L.
- Beta 2 Microglobulin 3.4 µg/mL.
- Immunoglobulin A 0.25 g/L.
- M Protein 3.5 g/dL.
- Blood Urea Nitrogen 6.07 mmol/L.
- Glucose 9.85 mmol/L.
- Creatinine 118 µmol/L.

Other clinical attributes
- Day -4: Weight: 102 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_2226_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2226_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
